Somatic mutation profile of tumor specimen TCGA-PL-A8LX-01A (aliquot TCGA-PL-A8LX-01A-11D-A41F-09) from TCGA case TCGA-PL-A8LX, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 35.2 years (12,840 days).
Specimen TCGA-PL-A8LX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 190d78c9-00d4-489c-b8e1-9632cd8a0043.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-PL-A8LX-10A (Blood Derived Normal), aliquot TCGA-PL-A8LX-10A-01D-A41F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fcf11f26-a91b-42f0-acf8-067256a48f9c

The open-access MAF lists 33 somatic variants for this specimen: 25 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 22, Silent 8, Frame Shift Ins 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC3 | c.4207C>T p.H1403Y | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV99559253; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4021G>A p.V1341M | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99783545; called by muse, mutect2, varscan2
- ATRN | c.2594C>A p.S865Y | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99497282; called by muse, varscan2
- C10orf71 | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.027); catalogued as COSV100110237; called by muse, mutect2, varscan2
- CYP2J2 | c.358A>G p.I120V | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.77); PolyPhen benign (0.009); catalogued as COSV100968041; called by muse, mutect2, varscan2
- DEPDC1 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.437); catalogued as rs758121846, COSV63958152; called by muse, mutect2, varscan2
- DUS2 | c.379G>C p.G127R | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100732525; called by muse, mutect2, varscan2
- EPPIN | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as rs1380476105, COSV100323250; called by muse, mutect2, varscan2
- FASN | c.7390C>G p.L2464V | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.659); catalogued as COSV100147874; called by muse, mutect2, varscan2
- HLA-F | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.077); catalogued as rs541971824, COSV99466056; called by muse, mutect2, varscan2
- ILF2 | c.937A>G p.T313A | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.863); catalogued as COSV100721949; called by muse, mutect2, varscan2
- KCNJ5 | c.1027T>C p.F343L | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.996); catalogued as COSV100610699; called by muse, mutect2, varscan2
- KMT2C | c.4432C>T p.Q1478* | Nonsense Mutation (SNP) | VAF 21/83 reads (25%) | catalogued as COSV51297329; called by muse, mutect2, varscan2
- LAMA1 | c.4973C>T p.A1658V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV67543822; called by mutect2, varscan2
- MROH2B | c.788T>A p.L263H | Missense Mutation (SNP) | VAF 64/117 reads (55%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.789); catalogued as COSV101270711; called by muse, mutect2, varscan2
- NME3 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs145911685; called by muse, varscan2
- OSBPL8 | c.2069T>A p.V690E | Missense Mutation (SNP) | VAF 6/117 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99675120; called by muse, mutect2
- RFTN2 | c.1393C>A p.L465M | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.179); catalogued as COSV99695665; called by muse, mutect2, varscan2
- SNRNP48 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100673006; called by muse, mutect2, varscan2
- SUN5 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.253); catalogued as rs759594105, COSV62180718; called by muse, mutect2, varscan2
- TRAPPC2L | c.205G>C p.V69L | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.417); catalogued as COSV51935792, COSV99243214; called by muse, mutect2, varscan2
- VNN1 | c.404T>C p.V135A | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV100907741; called by muse, mutect2, varscan2
- ZNF470 | c.1358A>T p.Y453F | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.151); catalogued as COSV100401258; called by muse, mutect2, varscan2
- KMT2C | c.8470dup p.T2824Nfs*9 | Frame Shift Ins (INS) | VAF 16/52 reads (31%) | called by mutect2, pindel, varscan2
- YLPM1 | c.490dup p.Y164Lfs*78 | Frame Shift Ins (INS) | VAF 30/57 reads (53%) | called by mutect2, pindel, varscan2
- ABCA13 | c.8940G>A p.A2980= | Silent (SNP) | VAF 33/74 reads (45%) | catalogued as rs750609118, COSV71287131; called by muse, mutect2, varscan2
- AGO4 | c.1428C>T p.P476= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV100942980; called by muse, mutect2, varscan2
- ATRN | c.2595C>T p.S865= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as rs6107315, COSV99497284; called by muse, varscan2
- CD8A | c.561G>A p.A187= | Silent (SNP) | VAF 6/100 reads (6%) | catalogued as COSV52157908, COSV99374451; called by muse, mutect2
- CRB2 | c.153C>T p.T51= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as rs759815636, COSV63502083; called by muse, mutect2, varscan2
- IDH3B | c.507G>T p.G169= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV100250147; called by mutect2, varscan2
- MDH2 | c.441C>G p.T147= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as COSV100242702; called by muse, mutect2, varscan2
- UBR5 | c.8052A>G p.E2684= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as COSV99641058; called by muse, mutect2
